Surgical pathology report (de-identified scan), TCGA case TCGA-36-1570, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site BC Cancer Agency, specimen TCGA-36-1570-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Consultation Report

TCGA-36-1570

Case Number:
Collect Date:
Receive Date:
Date Reported:

Patient's Name:
MRN:
PHN:
DOB/Gender:
Ordering Physician:

Final Diagnosis:

1. Ovaries, fallopian tubes, and omental cake: All show involvement by high grade papillary serous carcinoma
- (a) FIGO tumor grade 3/3
- (b) Foci of lymphovascular invasion are identified
- (c) Largest omental tumor nodule measures 3.0 cm in maximum dimension
- (d) Tubal intraepithelial carcinoma present in fimbria of right fallopian tube
- (e) Please see Comment
2. Uterus and cervix, and specimen submitted as "cul-de-sac":
- (a) Numerous deposits of high grade papillary serous carcinoma involving the uterine serosa and cul-de-sac
- (b) Disordered proliferative endometrium with focal simple hyperplasia
- (c) Unremarkable cervix
2. Peritoneal fluid: Positive for malignant cells, compatible with high grade serous carcinoma

Final Diagnosis Comment:

The bulk of disease involves the ovaries and omentum, with tubal involvement limited mostly to the fallopian tube surfaces. However, foci of tubal intraepithelial carcinoma are identified within the fimbria of the right fallopian tube. This finding raises the possibility of dissemination from a right fallopian tube primary; a primary ovarian or peritoneal serous carcinoma are also possible.

- Ovarian Ca
- A. L tube and ovary
- B. R tube and ovary
- C. Uterus and cervix
- D. Cul-de-sac
- E. Omental cake

Specimens Received:

- A: left tube + ovary
- B: right tube + ovary
- C: uterus + cervix
- D: cul de sac
- E: omental cake

Gross Description:

Specimen is received in five containers each labelled with the patient's name.

Container "A" is labelled "left tube and ovary" and consists of an ovarian mass with multiple grey-white nodules in the outer surface of the ovary and fallopian tube. The ovarian mass measures 7.5 x 4.0 x 8.0 cm and the fallopian tube measures 3.5 x 0.2 cm in diameter. The cut surface of the tumour is solid and partially cystic. The solid part represents approximately 85% of the tumour. Representative sections are submitted as follows:

"A1-A3" -ovarian tumour
"A4-A5" -fallopian tube

Container "B" is labelled "right tube and ovary" and consists of an ovarian mass with multiple grey-white nodules on the outer surface of the ovary and

[page 2 of 2]
fallopian tube. The ovarian mass measures 9.5 x 5.5 x 3.0 cm. The fallopian tube measures 3.5 x 0.2 cm in diameter. The cut surface of the mass is solid and partially cystic. The solid part is homogenous, grey-white and represents approximately 80% of the tumour. Representative sections are submitted as follows:

"B1-B3" -ovarian tumour
"B4" -fallopian tube

Container "C" is labelled "uterus and cervix" and consists of a total hysterectomy specimen measuring 9.0 cm from corpus to cervix, 4.5 cm from cornu to cornu and 3.5 cm from anterior to posterior. The cervix measures 3.0 cm in length. The os is slit in shape and measures 0.4 cm. The uterus shows multiple grey-white nodules on the serosal surface ranging from 0.1-0.3 cm in diameter, and thickening of the anterior peritoneal reflexion which measures 1.2 cm in thickness. The endocervix shows multiple cysts with mucoid material, otherwise the endocervix and exocervix are grossly unremarkable. Both anterior and posterior endometrium are grossly unremarkable. The myometrium is 2.0 cm in thickness with one small fibroid measuring 1.0 cm in the anterior myometrium and representative sections are submitted as follows:

"C1-C2" -anterior ecto/endocervix
"C3" -thickened anterior peritoneal reflexion
"C4-C5" -posterior ecto/endocervix
"C6-C7" -anterior endometrium/myometrium
"C8-C9" -posterior endometrium/myometrium
"C10" -cul-de-sac
"C11-C12" -the serosal nodule

Container "D" is labelled "cul-de-sac" and consists of grey-white nodular soft tissue measuring 2.5 x 2.5 x 0.8 cm and the tissue is submitted in toto in cassette "D1".

Container "E" is labelled "omental cake" and consists of omental fat with multiple grey-white nodules. The specimen measures 6.0 x 3.5 x 1.5 cm. The grey-white nodules range in size from 0.6 to 3.0 cm in diameter. Representative sections are submitted as "E1" and "E2".

Source: NCI Genomic Data Commons file 287bcc1e-2a09-4eb1-93de-006e1f960814 (TCGA-36-1570.F83833F4-A820-4FB9-A040-C238084976C3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).